Gene-level copy-number profile of tumor specimen HCM-SANG-1318-C20-06A-01D-A80T-32 from HCMI case HCM-SANG-1318-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-1318-C20-06A-01D-A80T-32: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e1e65ed9-2489-4d9e-9ea4-23b6f767989b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1318-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/9065ea8e-c545-414b-bf30-150dfb35c098

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 1,365; copy number 2: 24,115; copy number 3: 20,968; copy number 4: 7,265; copy number 5: 3,061; copy number 6: 3; copy number 7: 1,944; copy number 8: 153.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:15,282,557–15,722,608, 22 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1.
- chr22:18,715,815–18,757,906, 2 genes: PPP1R26P4, FAM230E.
- chr22:18,794,414–18,794,804, 1 gene (within-gene range 0–2): AC008132.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,161 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,659,467–32,668,383, 2 genes, copy number 6: HLA-DQB1, HLA-DQB1-AS1.
- chr7:37,032–159,233,377, 2,933 genes, copy number 5–8 (broad region; genes not listed).
- chr12:12,310–38,133, 3 genes, copy number 7: DDX11L8, WASH8P, FAM138D.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 5 (broad region; genes not listed).
- chr20:25,611,153–26,251,546, 26 genes, copy number 7: RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr20:30,294,550–64,327,972, 867 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 95. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
